Gene-level copy-number profile of tumor specimen TCGA-GN-A262-06A from TCGA case TCGA-GN-A262, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 55.2 years (20,147 days).
Specimen TCGA-GN-A262-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.951bc040-ed04-477b-a8e9-527f9d79124b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-GN-A262-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 815 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/99fbbf5a-a922-43c4-88e2-02386db6e5b2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 26; copy number 1: 16,634; copy number 2: 41,084; copy number 3: 456; copy number 4: 1,608.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-GN-A262-06A-11D-A194-01): tumor purity 1, ploidy 1.71, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 26 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:151,949,338–152,225,870, 8 genes: AC097375.4, AC097375.3, RNA5SP169, AC097375.5, LINC02273, AC079340.3, AC079340.1, AC079340.2.
- chr6:130,573,996–130,574,112, 1 gene: Y_RNA.
- chr10:87,503,881–88,259,372, 17 genes: MIR4678, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN, PTEN, AC063965.2, RPL11P3, AC063965.1, MED6P1, AL353149.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 16,345. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
